Gene-level copy-number profile of tumor specimen TCGA-K4-A3WS-01A from TCGA case TCGA-K4-A3WS, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 66.0 years (24,124 days).
Specimen TCGA-K4-A3WS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.efbaac50-ae3f-443a-867f-588674ffc9e8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-K4-A3WS-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8d61307c-a945-4881-949c-53f740fc3000

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 66; copy number 1: 740; copy number 2: 10,871; copy number 3: 18,753; copy number 4: 14,942; copy number 5: 6,182; copy number 6: 6,002; copy number 7: 1,205; copy number 8: 870; copy number 9: 103; copy number 14: 75.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-K4-A3WS-01A-11D-A22Y-01): tumor purity 0.4, ploidy 5.35, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 63 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,638,285–26,118,408, 43 genes: H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1, RMRPP5, RN7SKP120, AL353730.1, TUSC1, LINC01241, FAM71BP1, AL353753.1.
- chr10:116,538,183–117,279,430, 20 genes (within-gene range 0–3): RNU6-1090P, PNLIP, PNLIPP1, PNLIPRP1, PNLIPRP2, C10orf82, AC016825.1, HSPA12A, RPL5P27, ENO4, SHTN1, AC023283.1, AC012308.1, VAX1, MIR3663HG, MIR3663, RPL12P26, KCNK18, AL731557.1, SLC18A2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,253 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:159,535,078–177,437,880, 430 genes, copy number 8 (broad region; genes not listed).
- chr1:178,090,677–197,009,678, 268 genes, copy number 8 (broad region; genes not listed).
- chr1:236,215,101–242,524,697, 97 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr3:110,527,482–117,139,389, 106 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr3:143,265,222–143,848,485, 1 gene, copy number 8 (within-gene range 5–8): SLC9A9.
- chr3:143,342,246–153,377,562, 153 genes, copy number 7–8 (broad region; genes not listed).
- chr3:153,431,856–153,607,479, 3 genes, copy number 7: LINC02877, RNU6-901P, Y_RNA.
- chr3:158,696,892–168,928,598, 107 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr3:186,717,348–198,222,513, 263 genes, copy number 7 (broad region; genes not listed).
- chr4:49,096–781,859, 35 genes, copy number 7: BNIP3P41, ZNF595, AC253576.1, ZNF718, AC253576.2, AC108475.1, ZNF876P, AC079140.3, AC079140.5, ZNF732, AC079140.6, AC079140.4, ZNF141, AC079140.1, AC079140.2, MIR571, AC092574.2, ZNF519P4, AC092574.1, ABCA11P, ZNF721, PIGG, TMEM271, AC116565.1, PDE6B, PDE6B-AS1, AC107464.2, ATP5ME, MYL5, SLC49A3, PCGF3, AC107464.1, AC139887.4, AC139887.2, AC139887.1.
- chr4:4,894,182–7,112,399, 44 genes, copy number 7: LDHAP1, RN7SKP113, CYTL1, STK32B, Y_RNA, RN7SKP275, LINC01587, EVC2, EVC, CRMP1, C4orf50, MIR378D1, JAKMIP1, AC092442.1, AC113615.2, LINC02495, AC113615.1, AC116317.2, WFS1, AC116317.1, PPP2R2C, MAN2B2, MRFAP1, LINC02482, AC093323.4, AC093323.1, LINC02481, AC093323.2, S100P, AC093323.3, MRFAP1L1, BLOC1S4, AC106045.1, KIAA0232, TBC1D14, AC097382.3, AC097382.1, RN7SKP292, AC097382.2, CCDC96, TADA2B, GRPEL1, LINC02447, RN7SKP36.
- chr4:64,836,361–65,705,553, 10 genes, copy number 7: AC104689.2, LINC02232, AC107058.1, EFL1P2, AC096754.1, LINC02835, EPHA5, AC115223.1, EPHA5-AS1, AC104137.1.
- chr10:44,712–14,462,142, 250 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr10:47,300,197–48,119,455, 28 genes, copy number 8: GDF10, GDF2, RBP3, ZNF488, ANXA8, AL591684.3, FAM25G, AL591684.1, AGAP9, AL591684.2, RNA5SP312, BMS1P2, BX547991.1, DUSP8P1, CTSLP2, LINC02675, SHLD2P3, RN7SL453P, RHEBP2, FO681492.1, AC245041.2, NPY4R2, AC245041.1, FAM25C, AGAP12P, RNA5SP315, BMS1P7, PTPN20CP.
- chr12:92,420,094–93,215,679, 18 genes, copy number 9: CLLU1-AS1, CLLU1, AC063949.2, LINC02397, AC063949.1, PLEKHG7, EEA1, AC026111.1, HNRNPA1P50, RNU6-1329P, LINC02413, AC138123.1, Y_RNA, AC021646.1, RPL41P5, AC138123.2, NACAP8, LINC02412.
- chr12:132,196,372–133,214,832, 54 genes, copy number 8: GALNT9, AC138466.4, AC148477.3, AC148477.2, AC148477.5, AC148477.4, AC148477.1, AC148477.7, AC148477.10, AC148477.8, AC148477.6, AC148477.9, AC148476.1, AC079031.1, AC079031.2, FBRSL1, AC131212.3, AC131212.2, MIR6763, AC131212.1, LRCOL1, P2RX2, AC131212.4, POLE, PXMP2, AC135586.2, PGAM5, RNA5SP379, ANKLE2, AC135586.1, GOLGA3, CHFR, RPS11P5, RNU6-327P, AC127070.4, AC127070.1, AC127070.3, AC127070.2, ZNF605, NANOGNBP2, ZNF26, RNU4ATAC12P, ZNF84-DT, PTP4A1P2, ZNF84, AC073911.1, AC073911.2, ZNF140, ZNF891, AC026786.2, RPL23AP67, ZNF10, AC026786.1, ZNF268.
- chr17:21,614,487–22,606,703, 32 genes, copy number 9 (within-gene range 3–9): AC233702.1, AC233702.4, AC233702.9, KCNJ18, AC243725.1, ABBA01006766.1, NCOR1P2, UBBP4, FTLP13, LINC02002, AC138761.1, AC138761.2, FAM27E5, AC087575.1, FLJ36000, AC132825.3, AC132825.4, MTND6P35, MTCYBP13, MTRNR2L1, AC132825.2, MTND1P15, MTND2P13, AC132825.1, NMTRS-TGA3-1, MTATP6P3, MTCO3P13, AC132825.6, AC132825.7, AC132825.5, AC131055.2, AC131055.1.
- chr18:8,360,820–10,552,764, 58 genes, copy number 8: AP001094.3, AP001094.2, AP001094.1, COP1P1, RN7SL50P, THEMIS3P, AKR1B1P6, RAB12, AP001793.1, TOMM20P3, GACAT2, MTCL1, Y_RNA, AP000864.1, AP001531.1, AP005899.2, RPS4XP19, NDUFV2, AP005263.1, AP005899.1, NDUFV2-AS1, ANKRD12, Y_RNA, Y_RNA, AP001033.2, AP001033.1, TWSG1, AP001033.3, AP005432.2, RALBP1, AP005432.1, RNU2-27P, PPP4R1, AP001381.1, PPP4R1-AS1, RNU6-903P, LINC02856, KRT18P8, RAB31, AP000902.1, ZNF415P1, RN7SL862P, AC006238.2, RNA5SP449, PIGPP4, TXNDC2, AC006238.1, VAPA, RNA5SP450, AP005271.1, AP005209.2, AP005209.1, AP006219.1, AP006219.2, LINC01254, AP006219.3, APCDD1, NAPG.
- chr19:19,254,748–21,852,125, 127 genes, copy number 9–14 (broad region; genes not listed).
- chr19:21,940,820–21,941,533, 1 gene, copy number 9: MTDHP2.
- chr22:20,394,115–22,588,688, 168 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 332. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
